Surgical pathology report (de-identified scan), TCGA case TCGA-91-8496, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-8496-01A (Primary Tumor).

[page 1 of 3]
Operative Procedure:

Left thoracotomy, lobectomy

Specimen Received:

- A: Inferior pulmonary ligament lymph node
- B: Left lower lobe
- C: Anterior mediastinal lymph node
- D: Subcarinal lymph node
- E: A-P window lymph node
- F: Intra pulmonary lymph node
- G: Tracheobronchial lymph node

Final Pathologic Diagnosis:

A. Lymph node, inferior pulmonary ligament:
Benign pleural tissue.

B. Lung, left lower lobe, lobectomy:

Adenocarcinoma, well differentiated with predominantly bronchioalveolar growth pattern

Six lymph nodes negative for metastatic carcinoma (0/6).

See Synoptic report.

Lung cancer synoptic report (includes parts B, C, D, E, F, G)

Specimen: Lung-left lower lobe

Procedure: Lobectomy

Specimen laterality: Left

Tumor site: Left lower lobe of lung

Specimen integrity: Intact

Tumor size: 3.7 cm (greatest dimension)

Tumor focality: Unifocal

Tumor histologic type: Adenocarcinoma, with predominantly bronchioalveolar growth pattern and focal invasion

Tumor grade: Well-differentiated

Visceral pleura invasion: No

Tumor extension: Not identified

Margins:

Bronchial margin: Uninvolved by invasive carcinoma

Vascular margin: Uninvolved by invasive carcinoma

Parenchymal margin: Not applicable

Parietal pleural margin: Not applicable

Chest wall margin: Not applicable

Other attached tissue margin: Not applicable

If all margins uninvolved by invasive carcinoma:

Distance of invasive carcinoma from closest margin: 17 mm

Specify margin: Bronchial

Treatment effect: Not applicable

[page 2 of 3]
Lymph-vascular invasion: Not identified

Pathologic Staging (pTNM):

TNM Descriptors: None known

Primary tumor (pT): p2a

Regional lymph nodes (pN): pNX

Number involved/examined: 0/13

Left lower lobe peribronchial: 0/6

Anterior mediastinal: 0/1

Subcarinal: 0/2

A-P window: 0/1

Intrapulmonary: 0/2

Tracheobronchial: 0/1

Distant metastasis (pM): Not applicable

Additional pathologic findings: None

C. Lymph node, anterior mediastinal, biopsy:

One lymph node negative for metastatic carcinoma (0/1).

D. Lymph node, subcarinal, regional resection:

Two lymph nodes negative for metastatic carcinoma (0/2).

E. Lymph node, A-P window, biopsy:

One lymph node negative for metastatic carcinoma (0/1).

F. Lymph node, intrapulmonary, regional resection:

Two lymph nodes negative for metastatic carcinoma (0/2).

G. Lymph node, tracheobronchial, biopsy:

One lymph node negative for metastatic carcinoma (0/1).

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Gross Description:

Received are seven formalin filled containers, all labeled with the patient's name.

Part A is additionally labeled "inferior pulmonary ligament lymph node" and consists of a single 1.1 x 0.9 x 0.3 cm pink-tan fibrofatty tissue. No definitive lymph nodes are identified. The tissue is submitted in its entirety in cassette A1.

Part B is additionally labeled "left lower lobe."

Specimen components and dimensions: The specimen consists of a 155 gram intact lobe of lung with overall dimensions of 14.5 x 8.5 x 3.5 cm. The specimen is received with multiple staple lines on one edge. The staple lines are removed and the parenchymal surface is inked in black.

Size, appearance, and location of tumor: A 3.7 x 2.9 x 2.5 cm, roughly circular white-tan mass appears to abut the pleural surface. The pleural surface is umbilicated in this area. Tumor focality is unifocal.

[page 3 of 3]
Distance to bronchial margin: 1.7 cm

Distance to pleural surface: The mass appears to abut the pleural surface.

Number and appearance of peribronchial lymph nodes: Six peribronchial lymph nodes up to 2.2 cm in greatest dimension are found.

Other findings: None.

Uninvolved lung: The uninvolved lung is red-brown and homogeneous.

Blocks submitted:

- B1 vascular margin;
- B2 bronchial margin;
- B3 mass to inked parenchymal margin;
- B4 mass to pleura;
- B5-6 additional mass;
- B7 uninvolved parenchyma;
- B8 one lymph node bisected;
- B9 five whole lymph nodes.

Please note, a portion of the mass was submitted for precision. Additionally, a portion of the mass was banked with the Tissue Bank

Part C is additionally labeled "anterior mediastinal lymph node" and consists of a 1.3 x 1.2 x 0.6 cm portion of fibrofatty tissue. The tissue is bisected to reveal a lymph node up to 1 cm in greatest dimension. The tissue is submitted in its entirety in cassette C1.

Part D is additionally labeled "subcarinal lymph node" and consists of a single 0.6 x 0.5 x 0.3 cm pink-tan irregular fibrofatty tissue. This is submitted in toto in cassette D1.

Part E is additionally labeled "AP window lymph node" and consists of a single 0.6 x 0.4 x 0.3 cm tan-brown lymph node. This is submitted in toto in cassette E1.

Part F is additionally labeled "intrapulmonary lymph node" and consists of two portions of pink-tan to red-brown fibrofatty tissue measuring 1.7 x 1.5 x 0.6 cm and 1.7 x 1.2 x 0.7 cm. The first tissue is trisected and submitted in its entirety in cassette F1. The second tissue is bisected and submitted in its entirety in cassette F2.

Part G is additionally labeled "tracheobronchial lymph node" and consists of a single 0.5 x 0.3 x 0.3 cm tan-brown lymph node. This is submitted in its entirety in cassette G1.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Source: NCI Genomic Data Commons file 4a82a8bf-6458-4b17-9320-e285e6dfe17d (TCGA-91-8496.D513E826-62F5-4E2D-95EF-7B48FEA0643A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).